Somatic mutation profile of tumor specimen C3N-01342-02 (aliquot CPT0088140009) from CPTAC case C3N-01342, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 68.3 years (24,941 days).
Specimen C3N-01342-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6ca33783-1ab0-4430-8703-8ebcab03d06b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01342-31 (Blood Derived Normal), aliquot CPT0088170002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/77e598a9-eee9-4315-8d24-dbbab7c98406

The open-access MAF lists 64 somatic variants for this specimen: 41 protein-altering or splice-affecting, 13 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 13, Frame Shift Del 6, Intron 4, RNA 3, Frame Shift Ins 2, Nonsense Mutation 2, In Frame Del 1, Splice Region 1, 3'Flank 1, Splice Site 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 211/512 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs121913412, COSV62687862, COSV62689580, COSV62714770; ClinVar: conflicting interpretations of pathogenicity / pathogenic /  other / likely pathogenic; called by muse, mutect2, varscan2
- ECEL1 | c.2023G>A p.A675T | Missense Mutation (SNP) | VAF 62/196 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs606231471, CM1410209; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 47/104 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 126/299 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.860C>G p.S287* | Nonsense Mutation (SNP) | VAF 79/179 reads (44%) | catalogued as rs863224909, COSV104426445, COSV64291895; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ATP6V0A1 | c.824C>T p.T275M | Missense Mutation (SNP) | VAF 16/293 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1226165648, COSV52876106; called by muse, mutect2
- CD109 | c.3680G>A p.R1227H | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.07); catalogued as rs775503130, COSV54650900, COSV54657900; called by muse, mutect2, varscan2
- CHST8 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 65/139 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1261984908, COSV52857526; called by muse, mutect2, varscan2
- CRTAC1 | c.346G>A p.G116R | Missense Mutation (SNP) | VAF 63/184 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769753665, COSV54003405; called by muse, mutect2, varscan2
- CSF1R | c.179T>C p.L60P | Missense Mutation (SNP) | VAF 89/461 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.973); catalogued as rs1308547474; called by muse, mutect2, varscan2
- DHRS7C | c.569C>T p.T190M (on ENST00000330255 / NM_001220493.2; = p.T189M on NM_001105571.3) | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs374278019; called by muse, mutect2, varscan2
- EPHA10 | c.716C>T p.T239M | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1489866196; called by muse, mutect2, varscan2
- GATAD2B | c.1520C>T p.T507M | Missense Mutation (SNP) | VAF 56/142 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.284); catalogued as rs778803201; called by muse, mutect2, varscan2
- GLYR1 | c.1132del p.R378Gfs*23 | Frame Shift Del (DEL) | VAF 34/108 reads (31%) | catalogued as rs780981191, COSV58927238, COSV58927479; called by mutect2, pindel, varscan2
- MN1 | c.1949C>T p.S650L | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.086); catalogued as rs1211157447; called by muse, mutect2, varscan2
- NIPA2 | c.277G>A p.V93M | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1248320043, COSV61682322; called by muse, mutect2, varscan2
- NLRX1 | c.1129G>A p.V377I | Missense Mutation (SNP) | VAF 201/527 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs773600089; called by muse, mutect2, varscan2
- PCDH15 | c.4262C>T p.A1421V | Missense Mutation (SNP) | VAF 144/334 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.21); catalogued as rs1329914600, COSV57262088; called by muse, varscan2
- PIK3R1 | c.1683dup p.R562Tfs*6 (on ENST00000521381 / NM_181523.3; = p.R292Tfs*6 on NM_181504.4) | Frame Shift Ins (INS) | VAF 58/191 reads (30%) | catalogued as COSV57130789; called by pindel, varscan2
- PIK3R1 | c.1727del p.T576Rfs*6 (on ENST00000521381 / NM_181523.3; = p.T306Rfs*6 on NM_181504.4) | Frame Shift Del (DEL) | VAF 48/144 reads (33%) | catalogued as COSV57141446; called by pindel, varscan2
- PLXNB2 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 102/213 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63784930; called by muse, mutect2, varscan2
- RYR3 | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 61/193 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66797254; called by muse, mutect2, varscan2
- THBS2 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 34/285 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs1390597704, COSV64680794; called by muse, mutect2, varscan2
- ZNF43 | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs141039974; called by muse, mutect2, varscan2
- ADGRB2 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ARHGEF38 | c.485T>A p.V162E | Missense Mutation (SNP) | VAF 79/174 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- FRA10AC1 | c.484_485del p.V162Rfs*16 | Frame Shift Del (DEL) | VAF 6/31 reads (19%) | called by mutect2, pindel
- ILF3 | c.1862dup p.G622Wfs*99 (on ENST00000590261 / NM_012218.4; = p.G622Wfs*67 on NM_004516.4) | Frame Shift Ins (INS) | VAF 57/172 reads (33%) | called by mutect2, pindel, varscan2
- MACF1 | c.16828_16830del p.K5610del (on ENST00000372915; = p.K3652del on NM_012090.5) | In Frame Del (DEL) | VAF 122/277 reads (44%) | called by pindel, varscan2
- MTFMT | c.18_20dup p.R7dup | In Frame Ins (INS) | VAF 14/51 reads (27%) | called by mutect2, pindel, varscan2
- MXRA7 | c.601C>T p.L201F | Missense Mutation (SNP) | VAF 55/147 reads (37%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NEURL2 | c.752T>A p.L251Q | Missense Mutation (SNP) | VAF 67/157 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDE1C | c.1176G>A p.M392I | Missense Mutation (SNP) | VAF 67/155 reads (43%) | SIFT tolerated (0.38); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- PDGFRB | c.1677G>A p.K559= | Splice Region (SNP) | VAF 47/100 reads (47%) | called by muse, mutect2, varscan2
- PTEN | c.433_440del p.F145Gfs*32 | Frame Shift Del (DEL) | VAF 162/378 reads (43%) | called by mutect2, pindel, varscan2
- TAC3 | c.162C>G p.H54Q | Missense Mutation (SNP) | VAF 134/348 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TNKS | c.22C>T p.Q8* | Nonsense Mutation (SNP) | VAF 39/85 reads (46%) | called by muse, mutect2, varscan2
- TRIM24 | c.323C>G p.P108R | Missense Mutation (SNP) | VAF 61/138 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- UNC13A | c.928del p.Y310Tfs*55 | Frame Shift Del (DEL) | VAF 67/183 reads (37%) | called by mutect2, pindel, varscan2
- USP47 | c.1030-2A>G p.X344_splice (on ENST00000399455 / NM_001372095.1; = p.X256_splice on NM_017944.4 and 3 other RefSeq transcripts) | Splice Site (SNP) | VAF 34/76 reads (45%) | called by muse, mutect2, varscan2
- ZFHX3 | c.8843del p.R2948Lfs*6 | Frame Shift Del (DEL) | VAF 90/280 reads (32%) | called by mutect2, pindel, varscan2
- BBS9 | c.1380C>T p.Y460= | Silent (SNP) | VAF 86/179 reads (48%) | catalogued as rs376024532; called by muse, mutect2, varscan2
- CCDC114 | c.1827C>T p.Y609= | Silent (SNP) | VAF 85/207 reads (41%) | called by muse, mutect2, varscan2
- CDC42BPA | c.3435A>T p.S1145= (on ENST00000334218 / NM_001366019.2; = p.S1132= on NM_003607.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/118 reads (31%) | called by muse, mutect2, varscan2
- CEMIP2 | c.3534G>A p.P1178= | Silent (SNP) | VAF 78/221 reads (35%) | catalogued as rs142314012, COSV65487935; called by muse, mutect2, varscan2
- COL6A3 | c.4494G>A p.P1498= | Silent (SNP) | VAF 251/520 reads (48%) | catalogued as rs374885393; called by muse, mutect2, varscan2
- ENTPD3 | c.24A>G p.Q8= | Silent (SNP) | VAF 84/233 reads (36%) | called by muse, mutect2, varscan2
- EPRS1 | c.1410A>G p.G470= | Silent (SNP) | VAF 41/206 reads (20%) | called by muse, mutect2, varscan2
- FLNC | c.7215G>A p.S2405= | Silent (SNP) | VAF 158/372 reads (42%) | catalogued as rs774019775, COSV57957666; ClinVar: benign; called by muse, mutect2, varscan2
- MYT1L | c.870G>A p.S290= | Silent (SNP) | VAF 113/275 reads (41%) | catalogued as rs369668763; called by muse, mutect2, varscan2
- PCDHA6 | c.2160G>A p.A720= | Silent (SNP) | VAF 133/305 reads (44%) | catalogued as rs1554132671, COSV65344702; called by muse, mutect2, varscan2
- TSPAN5 | c.324C>G p.A108= | Silent (SNP) | VAF 85/175 reads (49%) | called by muse, mutect2, varscan2
- TUBB4A | c.1146C>T p.S382= | Silent (SNP) | VAF 319/806 reads (40%) | catalogued as rs545249557; called by muse, mutect2, varscan2
- WNT7B | c.795G>A p.E265= | Silent (SNP) | VAF 84/238 reads (35%) | called by muse, mutect2, varscan2
- AC019294.1 | n.26C>T | RNA (SNP) | VAF 121/241 reads (50%) | called by muse, mutect2, varscan2
- CICP28 | chr7:56812199 G>A | 3'Flank (SNP) | VAF 29/67 reads (43%) | called by muse, mutect2, varscan2
- FUNDC2 | c.-39G>A | 5'UTR (SNP) | VAF 73/134 reads (54%) | catalogued as COSV100811857; called by muse, mutect2, varscan2
- GPM6A | c.-23+31413G>A | Intron (SNP) | VAF 56/189 reads (30%) | catalogued as rs1200775849, COSV99702939; called by muse, mutect2, varscan2
- MT1G | c.97+93G>A | Intron (SNP) | VAF 72/195 reads (37%) | catalogued as rs781673205; called by muse, mutect2
- NBPF25P | n.1316C>T | RNA (SNP) | VAF 241/590 reads (41%) | called by muse, mutect2, varscan2
- NVL | c.285-1185G>C | Intron (SNP) | VAF 14/63 reads (22%) | called by muse, mutect2, varscan2
- TPRX2P | n.506C>G | RNA (SNP) | VAF 77/182 reads (42%) | called by muse, mutect2, varscan2
- TTC27 | c.1233+1944G>T | Intron (SNP) | VAF 24/75 reads (32%) | called by muse, mutect2, varscan2
- ZNF778 | c.*5111C>T | 3'UTR (SNP) | VAF 256/562 reads (46%) | catalogued as rs952695628; called by muse, mutect2, varscan2
